Somatic mutation profile of tumor specimen C3N-02192-01 (aliquot CPT0209620006) from CPTAC case C3N-02192, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 66.2 years (24,166 days).
Specimen C3N-02192-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 144c770a-a540-4e08-9503-66e8e71895a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02192-71 (Blood Derived Normal), aliquot CPT0209970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8d23f37-1677-4fa3-9d73-a7f1526475a8

The open-access MAF lists 226 somatic variants for this specimen: 154 protein-altering or splice-affecting, 42 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 136, Silent 42, Nonsense Mutation 15, Intron 13, 3'UTR 5, RNA 4, Splice Region 3, 5'UTR 3, 3'Flank 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.2209G>T p.V737F | Missense Mutation (SNP) | VAF 11/182 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV60914113; called by muse, mutect2
- APP | c.630G>C p.W210C | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); catalogued as COSV100695846; called by muse, mutect2
- ATRNL1 | c.2006G>C p.R669T | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs1457762700; called by muse, mutect2
- BCL6 | c.1373C>T p.P458L | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.997); catalogued as rs1044213121, COSV51656398; called by muse, mutect2
- BRAT1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs757941515; called by mutect2, varscan2
- CADM1 | c.169G>T p.G57* | Nonsense Mutation (SNP) | VAF 16/306 reads (5%) | catalogued as COSV100522621; called by muse, mutect2
- CCDC136 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV52796362; called by muse, mutect2
- CDC14C | c.629C>T p.A210V (on ENST00000428251; = p.A103V on NM_152627.3) | Missense Mutation (SNP) | VAF 63/250 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.309); catalogued as rs764641402; called by muse, mutect2, varscan2
- CT47B1 | c.414C>A p.N138K | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64890468, COSV64891176; called by muse, mutect2
- DCAF4L2 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 21/331 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1483692110, COSV60478406; called by muse, mutect2
- FKBP10 | c.1283C>G p.A428G | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.841); catalogued as COSV54057765; called by muse, mutect2
- GALNT17 | c.1259C>A p.P420Q | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780748741, COSV61155190; called by muse, mutect2
- GAREM1 | c.1221G>T p.R407S | Missense Mutation (SNP) | VAF 15/346 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV52511852; called by muse, mutect2
- H3C4 | c.25C>A p.R9S | Missense Mutation (SNP) | VAF 11/220 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV61911635; called by muse, mutect2
- IKZF1 | c.1079G>C p.R360P | Missense Mutation (SNP) | VAF 156/483 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.82); catalogued as COSV58780961, COSV58791195; called by muse, mutect2, varscan2
- ITGB2 | c.801C>A p.F267L | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs1490453952; called by muse, mutect2
- KCNB1 | c.1295G>T p.R432L | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65571311; called by muse, mutect2
- KCNH5 | c.1465C>G p.R489G | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59777205; called by muse, mutect2
- KLHL14 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV63835918; called by muse, mutect2
- KRT1 | c.211G>T p.G71C | Missense Mutation (SNP) | VAF 40/721 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV52867300; called by muse, mutect2
- KRTAP19-1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 26/524 reads (5%) | SIFT tolerated, low confidence (0.62); PolyPhen probably damaging (0.977); catalogued as rs533482116; called by muse, mutect2
- LIMA1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV100372464; called by muse, mutect2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2
- NKX2-1 | c.236C>G p.S79W | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as CM146079, COSV100701734, COSV61390068; called by muse, mutect2
- NPHS2 | c.561G>T p.M187I | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV100858196; called by muse, mutect2
- OR1S2 | c.454A>T p.R152W | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV100224089; called by muse, mutect2
- PCDHB7 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 24/692 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs536617500; called by muse, mutect2
- PNPLA7 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 10/142 reads (7%) | catalogued as COSV53005594; called by muse, mutect2
- PPFIA1 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as rs750055227, COSV54134324; called by muse, mutect2, varscan2
- PTPRB | c.5228G>A p.R1743Q | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773098818; called by muse, mutect2, varscan2
- REG3A | c.253G>T p.G85* | Nonsense Mutation (SNP) | VAF 8/206 reads (4%) | catalogued as COSV59410149, COSV59410240; called by muse, mutect2
- RGS22 | c.3106C>T p.Q1036* | Nonsense Mutation (SNP) | VAF 13/133 reads (10%) | catalogued as COSV62661414; called by muse, mutect2
- RYR2 | c.6217T>C p.S2073P | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as COSV100772129; called by muse, mutect2
- SLC25A2 | c.274G>T p.V92F | Missense Mutation (SNP) | VAF 12/408 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs1240987809; called by muse, mutect2
- SLC7A4 | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100298806; called by muse, mutect2
- STMN2 | c.205C>G p.R69G | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.136); catalogued as rs755759470, COSV55220490; called by muse, mutect2
- TBXAS1 | c.566T>A p.V189E | Missense Mutation (SNP) | VAF 46/594 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54939244; called by muse, mutect2
- TFAP2B | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1205744904; called by muse, mutect2
- TMEM63B | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs907823038; called by muse, mutect2
- TRBV24-1 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 19/239 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs1162286758; called by muse, mutect2
- TSKS | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484531295; called by muse, mutect2
- TTC3 | c.1792C>T p.H598Y | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61290452; called by muse, mutect2
- ZFHX3 | c.5646C>G p.I1882M | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs763961705; called by muse, mutect2
- ZFP57 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.821); catalogued as rs1438833770; called by muse, mutect2
- A1BG | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 14/478 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2
- ABCB5 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2
- ABCB8 | c.1100G>C p.R367P (on ENST00000297504 / NM_001282291.2; = p.R350P on NM_007188.5) | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.062); called by muse, mutect2
- AC018630.4 | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.389); called by muse, mutect2
- ADAMTS20 | c.780C>A p.Y260* | Nonsense Mutation (SNP) | VAF 12/154 reads (8%) | called by muse, mutect2
- ADAMTSL4 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- ADGRL3 | c.167A>T p.E56V | Missense Mutation (SNP) | VAF 19/361 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); called by muse, mutect2
- AHNAK2 | c.1038C>G p.F346L | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- AKT2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 20/536 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- ANKRD30A | c.3602G>T p.R1201I (on ENST00000611781; = p.R1145I on NM_052997.2) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ANKS1A | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2
- ANLN | c.2137C>G p.Q713E | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.055); called by muse, mutect2
- ATF7IP | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 9/224 reads (4%) | called by muse, mutect2
- BPIFB2 | c.53T>A p.V18D | Missense Mutation (SNP) | VAF 8/229 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2
- CAPSL | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 116/320 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASQ2 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2
- CATSPER1 | c.2018G>T p.S673I | Missense Mutation (SNP) | VAF 46/628 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.132); called by muse, mutect2
- CCDC136 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 28/332 reads (8%) | called by muse, mutect2
- CFAP65 | c.346A>G p.I116V (on ENST00000341552 / NM_194302.4; = p.I51V on NM_152389.4) | Missense Mutation (SNP) | VAF 13/248 reads (5%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.017); called by muse, mutect2
- CLCN7 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL22A1 | c.2132G>T p.G711V | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL3A1 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2
- COQ8A | c.592A>T p.S198C | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- CYP11B1 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 29/592 reads (5%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.932); called by muse, mutect2
- DLGAP1 | c.1109C>A p.A370D | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); called by muse, mutect2
- EIF4G1 | c.4780G>T p.E1594* (on ENST00000346169 / NM_198241.3; = p.E1399* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 11/252 reads (4%) | called by muse, mutect2
- EVC | c.2787G>T p.K929N | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM47B | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); called by muse, mutect2
- FAT2 | c.7697T>A p.V2566E | Missense Mutation (SNP) | VAF 15/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FBN2 | c.7133G>A p.C2378Y | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FBXL19 | c.79G>T p.G27W | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- FERD3L | c.425C>A p.T142N | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FGF16 | c.367C>A p.L123I | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); called by muse, mutect2
- FPR1 | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2
- FRMD4B | c.1233A>T p.S411= | Splice Region (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- GCKR | c.1530T>G p.I510M | Missense Mutation (SNP) | VAF 7/183 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.292); called by muse, mutect2
- GNAL | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); called by muse, mutect2
- GPR173 | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HDAC9 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2
- HSPA1L | c.784G>T p.V262L | Missense Mutation (SNP) | VAF 34/517 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2
- IFI16 | c.118A>T p.R40* | Nonsense Mutation (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- ITGAE | c.3176T>A p.I1059N | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, mutect2
- ITIH6 | c.3488C>A p.S1163Y | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- KCND3 | c.757C>A p.R253S | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2
- KCNQ5 | c.2374C>T p.Q792* | Nonsense Mutation (SNP) | VAF 14/285 reads (5%) | called by muse, mutect2
- KIR3DL1 | c.304T>A p.S102T | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- KRT75 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 12/348 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LILRB1 | c.1492G>T p.A498S | Missense Mutation (SNP) | VAF 15/248 reads (6%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.972); called by muse, mutect2
- MAGEE1 | c.2702G>T p.W901L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- MAP2 | c.4929G>T p.K1643N | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MEX3A | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2
- MICALL1 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- MSC | c.197G>C p.S66T | Missense Mutation (SNP) | VAF 14/187 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.023); called by muse, mutect2
- MUC12 | c.964G>A p.A322T (on ENST00000379442; = p.A179T on NM_001164462.1) | Missense Mutation (SNP) | VAF 24/498 reads (5%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.833); called by muse, mutect2
- MUC16 | c.4009C>A p.Q1337K | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); called by muse, mutect2
- MUC17 | c.4756G>A p.V1586I | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- MYH3 | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 17/418 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2
- NPHS1 | c.635G>T p.R212M | Missense Mutation (SNP) | VAF 14/304 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.153); called by muse, mutect2
- NR2C1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- NTSR1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2
- NUDT10 | c.18C>A p.N6K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2
- OBSCN | c.9260C>A p.A3087D | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OGDH | c.1135G>T p.A379S | Missense Mutation (SNP) | VAF 21/498 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); called by muse, mutect2
- PAPPA | c.1945C>A p.P649T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- PCLO | c.3502G>T p.A1168S | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2
- PDE8B | c.469T>G p.Y157D | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- PDZRN3 | c.693C>A p.S231R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- PKP1 | c.1333C>A p.R445S | Missense Mutation (SNP) | VAF 26/455 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLPPR4 | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2
- PLXNA4 | c.4242C>A p.D1414E | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2
- PNPLA6 | c.1667G>T p.C556F (on ENST00000414982 / NM_001166111.2; = p.C508F on NM_006702.5) | Missense Mutation (SNP) | VAF 26/481 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.502); called by muse, mutect2
- POPDC2 | c.765G>C p.K255N | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PRSS55 | c.586C>G p.Q196E | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.675); called by muse, mutect2
- PTPRD | c.3937C>A p.H1313N | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
- RASD2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 19/400 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- RXRB | c.1006G>T p.V336L | Missense Mutation (SNP) | VAF 15/209 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- RXYLT1 | c.1073C>A p.T358K | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- SETD2 | c.6766G>T p.V2256F | Missense Mutation (SNP) | VAF 8/179 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- SIAE | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 13/360 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SIRPA | c.917A>G p.K306R | Missense Mutation (SNP) | VAF 25/472 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.076); called by muse, mutect2
- SLC17A3 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 16/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLIT3 | c.2480T>A p.V827E | Missense Mutation (SNP) | VAF 8/203 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.14); called by muse, mutect2
- SPAG1 | c.1220G>T p.G407V | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SPATA31A1 | c.3244A>T p.K1082* | Nonsense Mutation (SNP) | VAF 28/780 reads (4%) | called by muse, mutect2
- SPRED2 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE1 | c.471C>A p.S157R (on ENST00000367255 / NM_182961.4; = p.S164R on NM_033071.3) | Missense Mutation (SNP) | VAF 23/354 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2
- TAB3 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.044); called by muse, mutect2
- TAS2R1 | c.68C>A p.T23K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.158); called by muse, mutect2
- TBX22 | c.691A>T p.S231C | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.873); called by muse, mutect2
- TFAP2B | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 18/330 reads (5%) | called by muse, mutect2
- THBS2 | c.1302C>A p.I434= | Splice Region (SNP) | VAF 16/268 reads (6%) | called by muse, mutect2
- TPRG1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 6/142 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2
- TSEN34 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.157); called by muse, mutect2
- TSNARE1 | c.182G>T p.G61V | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- TTC28 | c.2980G>T p.A994S | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0.098); called by muse, mutect2
- UNC5D | c.2102G>C p.C701S | Missense Mutation (SNP) | VAF 29/393 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- USP31 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 7/201 reads (3%) | called by muse, mutect2
- USP7 | c.3061A>G p.M1021V | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2
- VPS13B | c.7739C>T p.S2580F | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- WAPL | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.054); called by muse, mutect2
- WASF2 | c.129G>T p.L43= | Splice Region (SNP) | VAF 16/287 reads (6%) | called by muse, mutect2
- WIPF2 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 11/279 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ZBBX | c.789G>T p.Q263H | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2
- ZNF112 | c.356G>C p.C119S (on ENST00000337401 / NM_001083335.2; = p.C113S on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.073); called by muse, mutect2
- ZNF239 | c.55G>A p.V19M | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2
- ZNF416 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ZNF420 | c.1519G>T p.E507* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- ZNF536 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF843 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ZNF91 | c.2255A>T p.N752I | Missense Mutation (SNP) | VAF 31/336 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.515); called by muse, mutect2
- ACADL | c.273A>G p.E91= | Silent (SNP) | VAF 17/351 reads (5%) | called by muse, mutect2
- ADAMTS12 | c.3753G>T p.L1251= | Silent (SNP) | VAF 42/411 reads (10%) | called by muse, mutect2, varscan2
- ADGRL4 | c.1629G>T p.V543= | Silent (SNP) | VAF 8/214 reads (4%) | called by muse, mutect2
- AHNAK2 | c.2409C>T p.V803= | Silent (SNP) | VAF 30/608 reads (5%) | called by muse, mutect2
- ARMC1 | c.771G>T p.R257= | Silent (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- CACNA1D | c.144A>G p.Q48= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- CAMK4 | c.372A>T p.G124= | Silent (SNP) | VAF 7/141 reads (5%) | called by muse, mutect2
- CUX1 | c.3111G>A p.Q1037= | Silent (SNP) | VAF 12/213 reads (6%) | called by muse, mutect2
- EHD2 | c.663C>T p.A221= | Silent (SNP) | VAF 8/130 reads (6%) | called by muse, mutect2
- EPPK1 | c.3798G>T p.V1266= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- EYA3 | c.387T>C p.P129= | Silent (SNP) | VAF 11/192 reads (6%) | called by muse, mutect2
- F11 | c.129C>T p.A43= | Silent (SNP) | VAF 20/488 reads (4%) | called by muse, mutect2
- GPR158 | c.2428C>A p.R810= | Silent (SNP) | VAF 15/303 reads (5%) | catalogued as COSV66264798; called by muse, mutect2
- HTR4 | c.957T>C p.F319= | Silent (SNP) | VAF 13/286 reads (5%) | called by muse, mutect2
- KCNJ5 | c.549G>A p.V183= | Silent (SNP) | VAF 12/204 reads (6%) | called by muse, mutect2
- KRTAP10-3 | c.519C>T p.P173= | Silent (SNP) | VAF 16/319 reads (5%) | catalogued as rs782266874, COSV59983328; called by muse, mutect2
- MEGF8 | c.8355C>A p.L2785= (on ENST00000251268 / NM_001271938.2; = p.L2718= on NM_001410.3) | Silent (SNP) | VAF 11/150 reads (7%) | called by muse, mutect2
- MEX3A | c.1113G>T p.P371= | Silent (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- MMD2 | c.690G>C p.G230= (on ENST00000404774 / NM_001100600.2; = p.G206= on NM_198403.4) | Silent (SNP) | VAF 20/514 reads (4%) | catalogued as COSV101287022; called by muse, mutect2
- MMP2 | c.606G>A p.G202= | Silent (SNP) | VAF 33/511 reads (6%) | catalogued as COSV54601750; called by muse, mutect2
- MYO10 | c.4485G>T p.V1495= | Silent (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- NFATC2 | c.919C>T p.L307= | Silent (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- NPAP1 | c.1239G>T p.L413= | Silent (SNP) | VAF 11/254 reads (4%) | called by muse, mutect2
- PCDHA6 | c.147G>T p.A49= | Silent (SNP) | VAF 13/350 reads (4%) | catalogued as rs782682272, COSV100972625; called by muse, mutect2
- PCDHB14 | c.1371C>A p.T457= | Silent (SNP) | VAF 26/768 reads (3%) | catalogued as rs782208211; called by muse, mutect2
- PRKD1 | c.651A>G p.T217= | Silent (SNP) | VAF 17/300 reads (6%) | called by muse, mutect2
- RHAG | c.918C>A p.V306= | Silent (SNP) | VAF 12/376 reads (3%) | catalogued as COSV57706410; called by muse, mutect2
- RPTN | c.246C>A p.V82= | Silent (SNP) | VAF 15/210 reads (7%) | called by muse, mutect2
- SETD4 | c.319C>T p.L107= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as COSV100145686; called by muse, mutect2
- SHANK3 | c.3852G>A p.S1284= | Silent (SNP) | VAF 31/567 reads (5%) | catalogued as rs770871753, COSV53189829; called by muse, mutect2
- SLC26A3 | c.804C>G p.V268= | Silent (SNP) | VAF 89/251 reads (35%) | called by muse, mutect2, varscan2
- SNAPC4 | c.4008G>A p.E1336= | Silent (SNP) | VAF 12/256 reads (5%) | called by muse, mutect2
- SOWAHC | c.861C>T p.L287= | Silent (SNP) | VAF 16/249 reads (6%) | catalogued as rs905867906; called by muse, mutect2
- SUPT6H | c.2955G>A p.L985= | Silent (SNP) | VAF 22/197 reads (11%) | called by muse, mutect2, varscan2
- TBX5 | c.1293C>T p.T431= | Silent (SNP) | VAF 30/456 reads (7%) | called by muse, mutect2
- TMEM132B | c.1011C>A p.V337= | Silent (SNP) | VAF 20/300 reads (7%) | catalogued as rs191597906; called by muse, mutect2
- TMEM132C | c.2259C>A p.P753= | Silent (SNP) | VAF 10/230 reads (4%) | called by muse, mutect2
- TRIP12 | c.3273T>C p.G1091= | Silent (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
- TRPM6 | c.4545G>T p.V1515= | Silent (SNP) | VAF 21/387 reads (5%) | called by muse, mutect2
- USP6NL | c.1821A>G p.V607= | Silent (SNP) | VAF 26/428 reads (6%) | called by muse, mutect2
- WDR97 | c.1758G>T p.S586= | Silent (SNP) | VAF 11/335 reads (3%) | called by muse, mutect2
- ZNF565 | c.954C>A p.P318= (on ENST00000355114; = p.P278= on NM_152477.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 14/332 reads (4%) | called by muse, mutect2
- ABCA11P | n.1204A>T | RNA (SNP) | VAF 22/352 reads (6%) | catalogued as rs782558821; called by muse, mutect2
- AC107023.1 | n.26-11377G>T | Intron (SNP) | VAF 7/128 reads (5%) | called by muse, mutect2
- AC114741.1 | n.460G>T | RNA (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- AC135782.1 | n.458C>A | RNA (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- AL353804.7 | chrX:73849420 G>T | 5'Flank (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- ASH1L | c.5828+4538C>T | Intron (SNP) | VAF 20/648 reads (3%) | catalogued as rs1243301091; called by muse, mutect2
- CLVS1 | c.-152+54C>T | Intron (SNP) | VAF 40/352 reads (11%) | catalogued as rs1261835411; called by muse, mutect2, varscan2
- CSNK1D | c.886-25C>T | Intron (SNP) | VAF 26/419 reads (6%) | catalogued as rs1182324957; called by muse, mutect2
- DNAH10 | c.9645-770T>C | Intron (SNP) | VAF 17/459 reads (4%) | called by muse, mutect2
- FEZ1 | c.-278C>T | 5'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- GLYCTK | c.*1986C>A | 3'UTR (SNP) | VAF 8/174 reads (5%) | catalogued as rs1309320687; called by muse, mutect2
- HOXA10 | c.*276C>A | 3'UTR (SNP) | VAF 28/739 reads (4%) | called by muse, mutect2
- HSD17B2 | c.664+125T>A | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- KIF1A | c.1181-10C>A | Intron (SNP) | VAF 17/239 reads (7%) | called by muse, mutect2
- LINC00574 | n.81G>A | RNA (SNP) | VAF 22/249 reads (9%) | called by muse, mutect2
- MECOM | c.-20G>T | 5'UTR (SNP) | VAF 10/244 reads (4%) | called by muse, mutect2
- MYL2 | c.354-42C>A | Intron (SNP) | VAF 18/597 reads (3%) | called by muse, mutect2
- P2RX1 | c.525-46G>A | Intron (SNP) | VAF 9/277 reads (3%) | called by muse, mutect2
- PDGFRA | c.2323+1155C>A | Intron (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- POLR2F | c.453-14933C>A | Intron (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- PRND | chr20:4732482 C>A | 3'Flank (SNP) | VAF 12/352 reads (3%) | called by muse, mutect2
- PYCR3 | c.-11G>A | 5'UTR (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- RAB6A | c.184-141A>T | Intron (SNP) | VAF 10/256 reads (4%) | called by muse, mutect2
- RN7SL484P | chr15:99792184 T>C | 3'Flank (SNP) | VAF 14/452 reads (3%) | called by muse, mutect2
- RN7SL759P | chr15:20572624 C>G | 3'Flank (SNP) | VAF 26/322 reads (8%) | called by muse, mutect2
- SLC29A3 | c.*671G>T | 3'UTR (SNP) | VAF 14/246 reads (6%) | called by muse, mutect2
- TOP3B | c.2108-274G>T | Intron (SNP) | VAF 14/281 reads (5%) | called by muse, mutect2
- XPNPEP3 | c.*11G>T | 3'UTR (SNP) | VAF 17/361 reads (5%) | catalogued as COSV64026860; called by muse, mutect2
- ZC3HAV1 | c.*17G>A | 3'UTR (SNP) | VAF 20/308 reads (6%) | catalogued as rs746117074, COSV54294245; called by muse, mutect2
- ZNF578 | chr19:52451309 C>A | 5'Flank (SNP) | VAF 17/318 reads (5%) | catalogued as COSV99989284; called by muse, mutect2
